Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A6DI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A6DI-01A (Primary Tumor).

SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: True vocal cord, left, biopsy

- Invasive moderately differentiated keratinizing squamous cell carcinoma
- p16 IHC and high risk HPV ISH stains pending, to be reported in an addendum

B: Tracheal lymph node, anterior, biopsy

- No tumor seen in one lymph node (0/1)

Clinical History:

The patient is a -year-old man with clinical squamous cell carcinoma of left true vocal cord with tracheal invasion and transglottic spread.

Gross Description:

Received are two appropriately labeled containers.

Specimen A:

SITE: "left true vocal cord"

METHOD: biopsy

MEASURE: 1.5 x 1.3 x 0.2 cm

COMMENT: aggregate of soft pink/tan tissue

BLOCK #: A1,

Specimen B:

SITE: "anterior tracheal node"

METHOD: biopsy

MEASURE: 0.9 x 0.5 x 0.4 cm

COMMENT: rubbery pink/yellow tissue; bisected

BLOCK#: B1,

Addendum

A: True vocal cord, left, biopsy

- Carcinoma is negative for p16 by immunohistochemistry and negative for high risk HPV by in situ hybridization. Appropriate controls are performed.

ICD-O-3

Carcinoma, squamous cell
keratinizing NOS
8071/3

Site GSCF
Larynx NOS
C32.9

Path
True vocal cord
C32.D

JW 5/21/13

HPV Discrepancy		

Source: NCI Genomic Data Commons file d78316af-44aa-4cf9-a3ee-99133398fe01 (TCGA-BA-A6DI.16D4CB9A-268D-416C-B9EC-685050C49BE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).